Somatic mutation profile of tumor specimen TCGA-DX-A6YQ-01A (aliquot TCGA-DX-A6YQ-01A-12D-A33E-09) from TCGA case TCGA-DX-A6YQ, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Fibromyxosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Age at diagnosis: 86.0 years (31,421 days).
Specimen TCGA-DX-A6YQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b532148a-40c4-4907-ad4c-80c1dc341cb1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A6YQ-10A (Blood Derived Normal), aliquot TCGA-DX-A6YQ-10A-01D-A33H-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2ffa907-b4fe-40d6-9ccb-2005b4fc0e4d

The open-access MAF lists 84 somatic variants for this specimen: 62 protein-altering or splice-affecting, 18 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 18, Nonsense Mutation 5, Intron 2, In Frame Del 1, 3'UTR 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRG4 | c.556C>A p.Q186K | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773335401, COSV99797062; called by muse, mutect2, varscan2
- ADSL | c.1438G>A p.A480T | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as COSV99342625; called by muse, mutect2, varscan2
- ANO7 | c.1689C>G p.I563M (on ENST00000274979; = p.I509M on NM_001370694.2) | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV99239584; called by muse, varscan2
- ASPH | c.1783A>G p.K595E | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.356); catalogued as COSV101064503; called by muse, mutect2, varscan2
- CALCR | c.237G>T p.W79C | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64012924; called by muse, mutect2, varscan2
- CAMTA1 | c.3193G>A p.G1065R | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1064796821, COSV100345003, COSV100352590; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC117 | c.231G>C p.E77D | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as COSV50770730, COSV99968965; called by muse, mutect2, varscan2
- CNTNAP4 | c.1778C>T p.S593L | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100273582; called by muse, mutect2, varscan2
- CSF2RB | c.2215G>C p.D739H | Missense Mutation (SNP) | VAF 98/130 reads (75%) | SIFT tolerated (0.22); PolyPhen benign (0.028); catalogued as rs1274444745, COSV99454078; called by muse, mutect2, varscan2
- CTCFL | c.1118G>T p.C373F | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.7); PolyPhen benign (0.171); catalogued as COSV99713387; called by muse, mutect2, varscan2
- CXCR2 | c.244G>A p.V82I | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as rs201754155, COSV59282517; called by muse, mutect2, varscan2
- DCX | c.155C>A p.A52D | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1556405160, COSV100576791; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOCK4 | c.578C>T p.T193I | Missense Mutation (SNP) | VAF 50/96 reads (52%) | SIFT tolerated (0.22); PolyPhen benign (0.104); catalogued as rs757120759, COSV101455841; called by muse, mutect2, varscan2
- DSCAM | c.5362G>A p.V1788I | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.972); catalogued as rs748431627, COSV101261657; called by muse, mutect2, varscan2
- ESX1 | c.1207T>A p.C403S | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as COSV101006518; called by muse, mutect2, varscan2
- FAM155A | c.1250T>A p.L417H | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65556781; called by muse, mutect2, varscan2
- FAM83B | c.1955A>G p.K652R | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV100175086, COSV60920419; called by mutect2, varscan2
- GABRD | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV101059585; called by muse, mutect2, varscan2
- GABRR1 | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 59/91 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201013212, COSV65619294; called by muse, mutect2, varscan2
- GBF1 | c.1662G>C p.E554D (on ENST00000369983 / NM_001377137.1; = p.E553D on NM_004193.3) | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.471); catalogued as COSV100890700; called by muse, mutect2, varscan2
- GJD2 | c.181G>T p.G61C | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99290932; called by muse, mutect2, varscan2
- HKDC1 | c.25T>C p.F9L | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100664805; called by muse, mutect2, varscan2
- HMCN1 | c.16332T>G p.H5444Q | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99636712; called by muse, mutect2, varscan2
- IGHA1 | c.778G>A p.V260M | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs773600381; called by muse, mutect2, varscan2
- IGSF1 | c.3713C>G p.S1238* | Nonsense Mutation (SNP) | VAF 8/59 reads (14%) | catalogued as COSV100811754, COSV100812395; called by muse, mutect2, varscan2
- IGSF1 | c.3519C>A p.F1173L | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.977); catalogued as COSV100812399, COSV63839221; called by muse, varscan2
- IGSF1 | c.3437C>A p.S1146* | Nonsense Mutation (SNP) | VAF 16/78 reads (21%) | catalogued as COSV100812400; called by muse, varscan2
- ITGB4 | c.4525G>T p.D1509Y | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as COSV99564914; called by muse, mutect2
- JAKMIP3 | c.2262G>T p.E754D | Missense Mutation (SNP) | VAF 38/49 reads (78%) | SIFT tolerated (0.18); PolyPhen benign (0.019); catalogued as COSV100060038; called by muse, mutect2, varscan2
- KRTAP24-1 | c.725G>A p.R242K | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); catalogued as COSV100447553; called by muse, mutect2, varscan2
- LCT | c.2066G>A p.R689H | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT tolerated (0.07); PolyPhen benign (0.411); catalogued as rs146706415; called by muse, mutect2, varscan2
- LRRC4B | c.1068G>C p.Q356H | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100976063, COSV65350288; called by muse, mutect2, varscan2
- MET | c.895A>T p.I299F | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV100577024, COSV100577444; called by muse, mutect2
- MLH1 | c.1510A>T p.T504S | Missense Mutation (SNP) | VAF 57/85 reads (67%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as COSV99212812; called by muse, mutect2, varscan2
- MTHFD2L | c.448C>T p.P150S (on ENST00000395759 / NM_001144978.2; = p.P92S on NM_001004346.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100306390; called by muse, mutect2, varscan2
- MYH13 | c.1465C>G p.Q489E | Missense Mutation (SNP) | VAF 33/303 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV99353502, COSV99355683; called by muse, mutect2, varscan2
- MYH4 | c.4555C>A p.Q1519K | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV55122030; called by muse, mutect2, varscan2
- NF2 | c.235A>T p.K79* | Nonsense Mutation (SNP) | VAF 32/42 reads (76%) | catalogued as COSV100099680, COSV58519896; called by muse, mutect2, varscan2
- NLRP9 | c.2933C>G p.P978R | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as COSV100243540; called by muse, mutect2, varscan2
- OR13A1 | c.434G>T p.C145F | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65573193; called by muse, varscan2
- PADI6 | c.489C>A p.C163* | Nonsense Mutation (SNP) | VAF 24/59 reads (41%) | catalogued as COSV100640036; called by muse, mutect2
- PCDHA4 | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.728); catalogued as COSV63540610, COSV63545846; called by muse, mutect2
- PGLYRP3 | c.812T>C p.I271T | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.584); catalogued as COSV99319988; called by muse, mutect2, varscan2
- PKD2L2 | c.105C>A p.Y35* | Nonsense Mutation (SNP) | VAF 40/152 reads (26%) | catalogued as COSV99296750; called by muse, mutect2, varscan2
- PLXNA3 | c.1789C>T p.P597S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63754744; called by mutect2, varscan2
- PTPRT | c.481T>C p.Y161H | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100630933; called by muse, mutect2, varscan2
- RANGAP1 | c.1757A>G p.K586R | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV100663845; called by muse, mutect2, varscan2
- SRGAP3 | c.2473C>A p.L825M | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.969); catalogued as COSV100841482; called by muse, mutect2, varscan2
- SRPK2 | c.1892G>A p.R631Q | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); catalogued as rs1331780321, COSV99995918; called by muse, mutect2, varscan2
- STC1 | c.478T>A p.Y160N | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99282750; called by muse, mutect2, varscan2
- TARS1 | c.1853C>T p.P618L | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs1451790654, COSV99466529; called by muse, mutect2, varscan2
- TGS1 | c.372A>G p.I124M | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.87); PolyPhen benign (0.288); catalogued as COSV99485817; called by muse, mutect2, varscan2
- TMEM169 | c.805A>T p.S269C | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99824677; called by muse, mutect2, varscan2
- UBE2U | c.345G>A p.M115I | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs750793454, COSV64281815; called by muse, mutect2, varscan2
- USP17L2 | c.872T>C p.L291P | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.776); catalogued as COSV100414778; called by muse, mutect2, varscan2
- VPS4A | c.538G>A p.V180M | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs573192094, COSV99652166; called by muse, mutect2, varscan2
- ZMAT1 | c.154C>A p.L52I | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.287); catalogued as COSV100858701, COSV100858956; called by muse, mutect2, varscan2
- ZNF225 | c.144G>T p.G48= | Splice Region (SNP) | VAF 13/56 reads (23%) | catalogued as rs944469371, COSV53472672, COSV99489632; called by muse, mutect2, varscan2
- ZNF225 | c.145C>T p.H49Y | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.435); catalogued as COSV99489633; called by muse, mutect2, varscan2
- ZNF80 | c.127G>A p.V43I | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV100352171; called by muse, mutect2, varscan2
- KMT2E | c.3714G>T p.K1238N | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.052); called by muse, mutect2
- SMARCA5 | c.400_402del p.N134del | In Frame Del (DEL) | VAF 39/118 reads (33%) | called by mutect2, pindel, varscan2
- ASMT | c.366C>T p.D122= | Silent (SNP) | VAF 53/66 reads (80%) | catalogued as rs151095769, COSV67109654; called by muse, mutect2, varscan2
- CPAMD8 | c.3009C>T p.P1003= (on ENST00000651564; = p.P956= on NM_015692.5) | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV101488615; called by muse, mutect2, varscan2
- CYP2A7 | c.1110G>A p.L370= | Silent (SNP) | VAF 20/296 reads (7%) | catalogued as COSV99394570; called by muse, mutect2
- DGAT1 | c.768C>G p.L256= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV100184215; called by muse, mutect2, varscan2
- FAM83F | c.327C>T p.P109= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV100329103; called by muse, mutect2, varscan2
- FGD3 | c.1848C>T p.S616= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as rs781723786, COSV100490950; called by muse, mutect2, varscan2
- FSTL4 | c.141T>C p.F47= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as COSV99533920; called by muse, mutect2, varscan2
- KCNJ16 | c.252G>A p.S84= | Silent (SNP) | VAF 28/40 reads (70%) | catalogued as rs775001497, COSV99388790; called by muse, mutect2, varscan2
- LMTK2 | c.4077C>T p.F1359= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as rs560743982, COSV99807904; called by muse, mutect2, varscan2
- MYOM2 | c.1215G>A p.P405= | Silent (SNP) | VAF 30/104 reads (29%) | catalogued as rs563008335, COSV50754142; called by muse, mutect2, varscan2
- NEFH | c.2310G>A p.A770= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as rs757096652, COSV100151875; called by muse, mutect2, varscan2
- OPALIN | c.147A>C p.L49= | Silent (SNP) | VAF 18/32 reads (56%) | catalogued as COSV100959705; called by muse, mutect2, varscan2
- OR12D3 | c.540G>A p.K180= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV101011491; called by muse, mutect2
- OR7C1 | c.789A>G p.A263= | Silent (SNP) | VAF 30/53 reads (57%) | catalogued as COSV99934973; called by muse, mutect2, varscan2
- PRSS1 | c.438C>T p.N146= | Silent (SNP) | VAF 24/43 reads (56%) | catalogued as rs1405172635, COSV100297674, COSV100298526; called by muse, varscan2
- STARD8 | c.1593G>A p.L531= | Silent (SNP) | VAF 49/76 reads (64%) | catalogued as COSV99367724; called by muse, mutect2, varscan2
- TCEA2 | c.270G>T p.R90= | Silent (SNP) | VAF 5/67 reads (7%) | catalogued as rs1342453227, COSV100200355; called by muse, mutect2
- UCP1 | c.36C>A p.T12= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as rs555213120, COSV99530447; called by muse, mutect2, varscan2
- NSUN5 | c.*72C>T | 3'UTR (SNP) | VAF 13/87 reads (15%) | catalogued as rs1554541063, COSV99392578; called by muse, mutect2, varscan2
- RIMS2 | c.4064-21190G>T | Intron (SNP) | VAF 18/49 reads (37%) | catalogued as COSV51709647; called by muse, mutect2, varscan2
- SNRPB | c.686-137G>A | Intron (SNP) | VAF 20/93 reads (22%) | catalogued as COSV100293524; called by muse, mutect2, varscan2
- ZNF578 | chr19:52451267 G>A | 5'Flank (SNP) | VAF 17/103 reads (17%) | catalogued as rs778432926, COSV56516171; called by muse, mutect2, varscan2
